Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5441, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5441-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Collected:

Received:

Case type: Surgical Case

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LARYNX, LARYNGECTOMY WITH RIGHT SELECTIVE AND LEFT RADICAL MODIFIED NECK DISSECTION: INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA INVOLVING MAINLY THE SUPRAGLOTTIS LESION, LEFT PIRIFORM SINUS AND EXTENDING TO THE EPIGLOTTIS TO INVOLVE THE FALSE AND TRUE VOCAL CORD.
TUMOR SIZE 5.0 X 3.0 CM (ESTIMATE GROSS).
TUMOR INVADES THE ANTERIOR SPACE.
Lymphovascular permeation present.
Margins of resection free of tumor.
Left modified radical neck dissection:
5/42 POSITIVE LYMPH NODES (MACROMETASTASIS; SIZE OF LARGE METASTATIC FOCUS 2.2 CM; NO EXTRACAPSULAR EXTENSION PRESENT; LEVEL 2 2-19 POSITIVE NODES; LEVEL 3 2/5 POSITIVE NODES; LEVEL 4 1/9 POSITIVE NODES; LEVEL 5 0/9)-PENDING ADDITIONAL DEEPER SECTIONS.
Right selective node dissection:
Twenty benign lymph nodes (0/20), pending additional sections.

GROSS DESCRIPTION

(A) TOTAL LARYNGECTOMY, LEFT RADICAL MODIFIED NECK DISSECTION, AND RIGHT SELECTIVE NECK DISSECTION - Total laryngectomy specimen with overall measurement of 10.0 x 6.5 x 4.5 cm. The left neck measures 12.5 x 6.0 x 3.0 and the right is 10.0 x 1.5 x 4.0 cm. A light tan ulcerated excavated mass involving mainly the left pyriform sinus and extending to the left supraglottis and epiglottis and involving the midline and 1/3 the left/right supraglottic and epiglottic area. Tumor extends deeply into the anterior space but does not involve margins of resection and measures approximately 5.0 x 3.0 x 2.5 cm. The left and infraglottic and the entire transglottic area on the right are free of tumor. Specimen submitted from right to left.

The right side neck dissection measures 2.5 x 8.0 x 1.0 cm. Multiple lymph nodes are found and submitted in toto for histologic evaluation.

The left modified radical neck dissection measures 11.0 x 7.0 x 2.0 cm and includes the sternocleidomastoid muscle which measures 7.0 cm in length and 4.0 cm in width and the jugular vein which measures 6.0 cm in length and 0.5 cm in width. This includes levels 2, 3, 4, and 5.

SECTION CODE: A1, normal thyroid; A2-A20, sequential sectioning of the tumor and adjacent mucosa from left to right. Level 2, right: A21, A22, one bisected lymph node; A23, two lymph nodes; A24, two lymph nodes. Level 3, right: A25, three lymph nodes; A26, three lymph nodes; A27, three lymph nodes. Level 4, right: A28, three lymph nodes; A29, three lymph nodes; A30, two lymph nodes. Level 2, left: A31, three lymph nodes; A32, three lymph nodes; A33, three lymph nodes; A34, three lymph nodes; A35, three lymph nodes; A36, one bisected lymph node; A37, representative section of a grossly positive lymph node

[page 2 of 4]
[REDACTED]

[REDACTED]

Surgical Pathology Report

[REDACTED]

[REDACTED]

(lymph node measures 1.4 cm and is totally grossly replaced by tumor). Level 3, left: A38, three lymph nodes; A39, three lymph nodes; A40, representative section of a grossly positive lymph node (lymph node grossly measures 2.2 cm); A41, two possible lymph nodes. Level 4, left: A42, two lymph nodes; A43, two lymph nodes; A44, representative section of a grossly positive lymph node (lymph node grossly measures 1.7 cm); A45, three lymph nodes; A46, one lymph node. Level 5, left: A47, one lymph node; A48, three lymph nodes; A49, one bisected lymph node; A50, three lymph nodes; A51, one lymph node. [REDACTED]

CLINICAL HISTORY

None given.

SNOMED CODES

T-24100, M-80703

[REDACTED]

[REDACTED]

[page 3 of 4]
Surgical Pathology Report

Collected:

Received:

Pathologist:

Case type: Surgical Case

ADDENDUM

COMMENT

Additional deeper sections on slides A27, A50 and A51 were reviewed. These sections show multiple benign lymph nodes with no evidence of metastatic carcinoma.

[page 4 of 4]
[REDACTED]

[REDACTED]

**Surgical Pathology
Report**

[REDACTED]

[REDACTED]

Collected: [REDACTED]
Received [REDACTED]

Pathologist:
Case type: Surgical Case

ADDENDUM #2

[REDACTED]

DIAGNOSIS

(A) LARYNGECTOMY WITH RIGHT SELECTIVE AND LEFT RADICAL MODIFIED NECK DISSECTION:
POORLY DIFFERENTIATED SQUAMOUS CARCINOMA INVADING THYROID CARTILAGE AND EPIGLOTTIC
CARTILAGE WITH EXTENSION TO THE SOFT TISSUES (EXTENSIVE PERINEURAL INVASION).

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 0c0d4867-5433-4473-9104-39bdde7d968f (TCGA-CV-5441.02C41AAE-DA7B-4FA9-BB52-70FF0791B3C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).